Somatic mutation profile of tumor specimen TCGA-DU-A5TS-01A (aliquot TCGA-DU-A5TS-01A-11D-A289-08) from TCGA case TCGA-DU-A5TS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 42.8 years (15,650 days).
Specimen TCGA-DU-A5TS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d53b5a0b-d2f1-4544-9aa2-f3bbe4489c7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TS-10A (Blood Derived Normal), aliquot TCGA-DU-A5TS-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ea35737-d9af-4ee3-a630-a2450993bd1a

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Splice Site 4, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PNP | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs104894460, CM012158, COSV100828934, COSV64092007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.3361C>T p.R1121C (on ENST00000280772 / NM_001320874.2; = p.R255C on NM_001149.3) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759013111, COSV55064344; called by muse, mutect2, varscan2
- ANKRD11 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as COSV56363394, COSV56371575; called by muse, varscan2
- ANKRD30A | c.3586G>T p.E1196* (on ENST00000611781; = p.E1140* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV64608794, COSV64613321; called by muse, mutect2, varscan2
- AP4B1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753402898, COSV56725548; called by muse, mutect2, varscan2
- CD2AP | c.1632+1G>A p.X544_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV63761352; called by muse, mutect2, varscan2
- CNGB1 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV51902435; called by muse, mutect2, varscan2
- DNMT3A | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444551068, COSV53036290; called by muse, mutect2, varscan2
- DSC1 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV57146494, COSV57147223; called by muse, mutect2, varscan2
- FAM220A | c.461G>C p.R154P | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs771917863, COSV57626663, COSV57627399; called by muse, mutect2
- KCNV2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.189); catalogued as rs767955052, COSV66056603; called by muse, mutect2, varscan2
- KLHL17 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs780395529, COSV58532376; called by muse, mutect2, varscan2
- LRRC3 | c.148T>C p.C50R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52399558; called by muse, mutect2, varscan2
- MYO7A | c.4858G>A p.E1620K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs768472164, COSV68685239; called by muse, mutect2, varscan2
- NAV3 | c.1976A>G p.D659G | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV57088814; called by muse, mutect2, varscan2
- NBEAL2 | c.7060C>T p.R2354C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs184366749, COSV99434158; called by muse, mutect2, varscan2
- NCAPD2 | c.2833G>C p.V945L | Missense Mutation (SNP) | VAF 148/266 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV59700427; called by muse, mutect2, varscan2
- NLRP13 | c.2282+1G>A p.X761_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as rs768101904, COSV61622492; called by muse, mutect2, varscan2
- PCNX2 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV50815519; called by muse, mutect2, varscan2
- PTER | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54346206; called by muse, mutect2, varscan2
- RABL6 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1260091297, COSV61036845; called by muse, mutect2, varscan2
- RHBDD1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773433822, COSV58125871; called by muse, mutect2, varscan2
- RXFP2 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs181937374, COSV53637072; called by muse, mutect2
- SEMA4A | c.1490G>T p.C497F | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61773104; called by muse, mutect2, varscan2
- SUFU | c.756+1G>T p.X252_splice | Splice Site (SNP) | VAF 37/111 reads (33%) | catalogued as CS153005, COSV64013898, COSV64015154; called by muse, mutect2, varscan2
- ULK1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1041786532, COSV100416448; called by muse, mutect2, varscan2
- ATRX | c.2663dup p.S889Lfs*8 | Frame Shift Ins (INS) | VAF 85/158 reads (54%) | called by mutect2, pindel, varscan2
- COP1 | c.1873_1874del p.W625Efs*17 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by pindel, varscan2
- IL19 | c.-2-1_1del | Splice Site (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- NCSTN | c.850_852del p.S284del | In Frame Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- ACLY | c.441C>T p.A147= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV61251219; called by muse, mutect2, varscan2
- ANKRD11 | c.483G>A p.V161= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs894039561, COSV56363400; called by muse, varscan2
- CACNA1B | c.3723G>A p.G1241= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53128921; called by muse, mutect2, varscan2
- HMCN1 | c.3939C>T p.G1313= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV54900316, COSV54910953; called by muse, mutect2, varscan2
- IGKV3-20 | c.6A>G p.E2= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs1222986401; called by muse, mutect2, varscan2
- KMT5A | c.714G>A p.R238= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV57863632; called by muse, mutect2, varscan2
- PKP4 | c.3537T>C p.Y1179= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as rs769528450, COSV61579071; called by muse, mutect2, varscan2
- RASSF9 | c.543T>C p.D181= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV63434465; called by muse, mutect2, varscan2
- NACA | c.71-4394C>G | Intron (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100771046, COSV63270696; called by muse, mutect2, varscan2
